Gene-level copy-number profile of tumor specimen ALCH-AEPF-TTP1-A from ALCHEMIST case ALCH-AEPF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.8 years (26,602 days).
Specimen ALCH-AEPF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6394378f-f700-4c99-bfcf-c501d3e07e8d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEPF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/826af828-66d5-4310-9a1c-46a5cbd63ed4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 2,380; copy number 2: 55,353; copy number 3: 530; copy number 4: 46; copy number 5: 2; copy number 6: 1; copy number 18: 5.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:183,895,900–183,910,936, 1 gene: CYP2AB1P.
- chr7:5,592,816–5,606,655, 1 gene: FSCN1.
- chr7:27,239,243–27,269,678, 4 genes: AC004080.1, EVX1-AS, EVX1, RPL35P4.
- chr7:56,360,362–56,365,270, 2 genes: SEPTIN14P24, CICP8.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–2): AL357936.1.
- chr11:45,885,651–45,918,812, 4 genes: MAPK8IP1, AC068385.1, C11orf94, PEX16.
- chr15:25,169,337–25,225,284, 31 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:4,331,549–4,425,705, 6 genes (within-gene range 0–2): PAM16, AC012676.1, CORO7-PAM16, AC012676.5, CORO7, VASN.
- chr16:67,929,614–67,944,131, 3 genes (within-gene range 0–2): AC040162.1, PSMB10, LCAT.
- chr17:183,824–191,587, 1 gene: LINC02091.
- chr17:39,619,613–39,622,770, 1 gene: AC087491.1.
- chr17:60,696,313–60,696,605, 1 gene (within-gene range 0–2): RN7SL606P.
- chr17:79,730,943–79,742,219, 1 gene: ENPP7.
- chr18:49,495,147–49,501,860, 2 genes: SRP72P1, LINC02837.
- chr22:17,734,138–17,779,481, 3 genes: BID, MIR3198-1, LINC00528.
- chr22:17,787,652–17,811,497, 2 genes (within-gene range 0–2): AC016026.1, AC016026.2.
- chr22:41,922,032–41,958,933, 4 genes: TNFRSF13C, MIR378I, CENPM, LINC00634.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,515,997–130,549,883, 5 genes, copy number 18: AC013269.2, Metazoa_SRP, CFC1B, AC013269.1, PRSS40B.
- chr21:43,414,483–43,427,131, 1 gene, copy number 6: SIK1.
- chr22:39,223,359–39,279,897, 2 genes, copy number 5: PDGFB, AL031590.1.

Autosomal genes at a single copy (total copy number 1): 2,370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
